Somatic mutation profile of tumor specimen C3N-02769-02 (aliquot CPT0205570009) from CPTAC case C3N-02769, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.9 years (19,701 days).
Specimen C3N-02769-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad265276-eed8-45c4-a2e1-bfb54bb61ada.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02769-71 (Blood Derived Normal), aliquot CPT0205620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e694708-12f5-4bbd-a8ac-a0aae7cd962e

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Intron 3, Frame Shift Ins 2, 3'UTR 2, RNA 1, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 77/198 reads (39%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1B | c.5479G>A p.V1827I | Missense Mutation (SNP) | VAF 98/316 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374147774; called by muse, mutect2, varscan2
- DGKB | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs765803079, COSV51781139; called by muse, mutect2
- DNMT3B | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 58/762 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM002946, COSV52415711; called by muse, mutect2
- EGFR | c.1994G>A p.G665D | Missense Mutation (SNP) | VAF 248/5273 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99286607; called by muse, mutect2
- FOXD4L5 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 195/1186 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.015); catalogued as rs758026813, COSV66240330; called by mutect2, varscan2
- HERC2 | c.9907G>A p.V3303M | Missense Mutation (SNP) | VAF 134/568 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757268665; called by muse, mutect2, varscan2
- HNF1B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 153/459 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs760239398; called by muse, mutect2, varscan2
- HS3ST3B1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1465414052; called by muse, mutect2, varscan2
- IARS2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs139651915; called by muse, mutect2, varscan2
- KRT2 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 394/810 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs375182516, COSV100548401, COSV100548729; called by muse, mutect2, varscan2
- MACF1 | c.12872C>T p.A4291V (on ENST00000372915; = p.A2224V on NM_012090.5) | Missense Mutation (SNP) | VAF 91/277 reads (33%) | catalogued as rs573837366, COSV57104402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEE1 | c.2686C>A p.Q896K | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV63910056; called by muse, mutect2
- MYO10 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs745913965; called by muse, mutect2, varscan2
- MYO15A | c.4264C>T p.Q1422* | Nonsense Mutation (SNP) | VAF 106/311 reads (34%) | catalogued as COSV52762448; called by muse, mutect2, varscan2
- PCYOX1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368423614, COSV104389253; called by muse, mutect2, varscan2
- PEAK1 | c.3571G>A p.D1191N | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs201535248, COSV56942968; called by muse, mutect2, varscan2
- PGR | c.1831G>C p.V611L | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99677589; called by muse, mutect2
- QPCTL | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV50004698; called by muse, mutect2, varscan2
- SEMA5A | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 53/534 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1407782671, COSV66789974; called by muse, mutect2
- SLC27A1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 206/675 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778973140; called by muse, mutect2, varscan2
- TMC2 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762767921; called by muse, mutect2, varscan2
- TUBA3C | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as rs756491837, COSV67139538; called by muse, mutect2, varscan2
- VASH2 | c.926G>A p.R309Q (on ENST00000517399 / NM_001301056.2; = p.R265Q on NM_024749.5) | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as rs1182716628, COSV99663533; called by muse, mutect2, varscan2
- ZNF469 | c.3667G>A p.A1223T (on ENST00000437464; = p.A1251T on NM_001367624.2) | Missense Mutation (SNP) | VAF 160/507 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs768287765; called by muse, mutect2, varscan2
- CYP4F12 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- E2F5 | c.320dup p.S108Vfs*15 | Frame Shift Ins (INS) | VAF 44/141 reads (31%) | called by mutect2, varscan2
- ERN1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- HERC2 | c.11164C>G p.R3722G | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IGHG1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 202/429 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- INTS3 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MLXIPL | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 159/762 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8S1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PLCZ1 | c.1361G>C p.G454A | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.2); called by muse, mutect2
- RBM15B | c.2132_2135del p.L711Qfs*17 | Frame Shift Del (DEL) | VAF 90/340 reads (26%) | called by mutect2, pindel, varscan2
- TMEM8B | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY9 | c.1803A>G p.S601= | Silent (SNP) | VAF 102/322 reads (32%) | called by muse, mutect2, varscan2
- ATAD3A | c.1398G>A p.R466= | Silent (SNP) | VAF 54/423 reads (13%) | called by muse, mutect2, varscan2
- EGFR | c.753C>T p.C251= | Silent (SNP) | VAF 362/980 reads (37%) | catalogued as rs1031220918; called by mutect2, varscan2
- GBP5 | c.327C>T p.N109= | Silent (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2, varscan2
- IRF4 | c.1122C>T p.H374= | Silent (SNP) | VAF 123/204 reads (60%) | catalogued as rs760994228, COSV66704965; called by muse, mutect2, varscan2
- KCNIP4 | c.567C>T p.Y189= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs758934908, COSV54844338; called by muse, mutect2, varscan2
- KLHL6 | c.66G>A p.G22= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as rs762467856; called by muse, mutect2, varscan2
- MANSC1 | c.1134C>A p.G378= | Silent (SNP) | VAF 48/492 reads (10%) | called by muse, mutect2
- RASGRP3 | c.1839C>A p.A613= (on ENST00000402538 / NM_001349975.2; = p.A612= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 115/379 reads (30%) | called by muse, mutect2, varscan2
- STRC | c.5046C>T p.G1682= | Silent (SNP) | VAF 130/675 reads (19%) | catalogued as rs1311508071; called by muse, varscan2
- TRIM71 | c.2001C>T p.I667= | Silent (SNP) | VAF 101/271 reads (37%) | catalogued as COSV67470340; called by muse, mutect2, varscan2
- ANKRD20A8P | n.1332A>G | RNA (SNP) | VAF 65/319 reads (20%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501319 del AG | 5'Flank (DEL) | VAF 50/116 reads (43%) | called by mutect2, pindel, varscan2
- CCDC177 | c.*615T>C | 3'UTR (SNP) | VAF 57/265 reads (22%) | catalogued as rs1166909096; called by muse, mutect2, varscan2
- DLC1 | c.1348+90501A>C | Intron (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- ISOC2 | c.*19G>A | 3'UTR (SNP) | VAF 6/57 reads (11%) | catalogued as rs563941545; called by muse, mutect2
- LIMA1 | c.1141-3353T>C | Intron (SNP) | VAF 36/325 reads (11%) | called by muse, mutect2, varscan2
- P3H1 | c.1569+555T>C | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- PIGA | c.-80C>T | 5'UTR (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
